Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HD, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HD-01A (Primary Tumor).

Synoptic translated report
University Pathology Institute

Site : Left lung superior lobe

☐ Central ☒ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size :

1. 9.2 x 6.0 x 5.2 cm

Visceral pleural invasion : ☒ Yes ☐ No ☐ NA

Chest wall invasion : ☒ Yes ☐ No ☐ NA

Histological diagnosis : Poorly differentiated squamous cell carcinoma

Node status : NO (0/10)

TNM : pT3 NO (0/10) G3 R0

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site: @ Lung, upper lobe C34.1

NO 2/1/13

Pathologist signature:

Date:

Source: NCI Genomic Data Commons file cd3491f3-f4a0-490f-a8de-c953be864433 (TCGA-NC-A5HD.414E245A-D9A7-4006-B197-656F8C6DB841.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).